Somatic mutation profile of tumor specimen TARGET-10-PAPZRB-09A (aliquot TARGET-10-PAPZRB-09A-01D) from TARGET case TARGET-10-PAPZRB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (927 days).
Specimen TARGET-10-PAPZRB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 626a0299-883b-48ce-b93f-1d933d768df4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPZRB-10A (Blood Derived Normal), aliquot TARGET-10-PAPZRB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/009dd5db-b6a3-475b-815c-0b4904fcb925

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, Intron 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRINP1 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as rs1453440054, COSV99775127; called by muse, mutect2, varscan2
- MAP3K6 | c.2999G>A p.R1000H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs930517859; called by muse, mutect2, varscan2
- NMI | c.372T>G p.H124Q | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1452437521, COSV54637987; called by muse, mutect2
- NCOR1 | c.6714_6715insGG p.P2239Gfs*55 | Frame Shift Ins (INS) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
- H4C6 | c.183G>A p.V61= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as rs775521933; called by muse, mutect2, varscan2
- IGLV4-60 | chr22:22162681 ins TCCTTCCCC | 3'Flank (INS) | VAF 18/54 reads (33%) | called by mutect2, pindel, varscan2
- PCLO | c.13300+173T>C | Intron (SNP) | VAF 26/64 reads (41%) | called by muse, varscan2
